Surgical pathology report (de-identified scan), TCGA case TCGA-50-5936, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5936-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: RIB, FIFTH, EXCISION –

- A. UNREMARKABLE BONE AND BONE MARROW WITH TRILINEAGE HEMATOPOIESIS.
- B. NO EVIDENCE OF MALIGNANCY.

PART 2: LYMPH NODE, INTRALOBAR, EXCISION –

ONE OF TWO IDENTIFIED LYMPH NODAL FRAGMENTS POSITIVE FOR METASTATIC ADENOCARCINOMA (1/2).

PART 3: LYMPH NODE, RIGHT MIDDLE LOBE, EXCISION –

THREE OF FOUR IDENTIFIED LYMPH NODAL FRAGMENTS POSITIVE FOR METASTATIC CARCINOMA (3/4).

PART 4: LUNG, RIGHT LOWER LOBE, LOBECTOMY AND INTRAOPERATIVE CONSULTATION –

- A. MUCINOUS ADENOCARCINOMA WITH ACINAR BRONCHIOLAR ALVEOLAR MICROPAPILLARY FEATURES (MEASURING 6.0 CM IN MAXIMUM DIMENSION).
- B. THE TUMOR INVOLVES THE OVERLYING VISCERAL PLEURA.
- C. THE TUMOR EXTENSIVELY INVOLVES THE ANGIOLYMPHATIC CHANNELS.
- D. SMALL PULMONARY VASCULATURE SHOWS THROMBOEMBOLIC PHENOMENON WITH SECONDARY PULMONARY INFARCTION.
- E. BRONCHIAL AND VASCULAR MARGINS SHOW NO EVIDENCE OF MALIGNANCY.
- F. FOUR OF SIX IDENTIFIED HILAR LYMPH NODES ARE POSITIVE FOR METASTATIC ADENOCARCINOMA (4/6) WITH PROMINENT EXTRACAPSULAR EXTENSION.
- G. TNM STAGE: T2, N2, MX.

PART 5: LYMPH NODE, LEVEL 7 (SUBCARINAL), EXCISION –

FIVE OF SIX SUBMITTED LYMPHOIDAL FRAGMENTS POSITIVE FOR METASTATIC ADENOCARCINOMA WITH EXTRACAPSULAR EXTENSION (5/6).

PART 6: LYMPH NODE, RIGHT PERITRACHEAL, EXCISION –

SINGLE IDENTIFIED LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA (1/1).

ADDENDA:

Addendum

Molecular Anatomic Pathology testing:

- A. **KRAS** Exon 1 mutation IS IDENTIFIED (Gly12Cys).
- B. **EGFR** Exon 19 mutation NOT identified.
- C. **EGFR** Exon 21 mutation NOT identified.

Note:

KRAS codon 12/13 mutations are found in approximately 10-30% lung adenocarcinomas and associated with history of smoking (1). **EGFR** exon 19 and 21 mutations are present in about 10% of non-Asians and up to 40% in the Asian population, common in non-smokers and associated with the tumor response to treatment with **EGFR** inhibitors (2). These mutations are mutually exclusive and their presence may have prognostic and/or therapeutic implications (3,4).

Sample Preparation and Gene Sequencing Analysis

For cytology samples, extraction of DNA was performed from the fluid or sample provided. For surgical specimens, tumor microdissection was performed. DNA was isolated using standard laboratory procedure. Optical density readings were obtained. For the detection of mutation, DNA was amplified with primers flanking exon 1 in the **KRAS** gene and exons 19 and 21 of the **EGFR** gene. Then, forward and reverse sequencing was performed using the BigDye Terminator Kit on ABI3130 (Applied Biosystems). The known hotspots were analyzed for the presence of mutations with Mutation Surveyor V3.01 (SoftGenetics).

Addendum

PROBE: Vysis LSI **EGFR** SpectrumOrange/ CEP 7 SpectrumGreen™ Probe ([REDACTED])

Fluorescence in-situ hybridization studies performed on the adenocarcinoma shows a ratio of **EGFR** gene to the centromere of chromosome 7 of 1.2 indicating **no EGFR amplification** in the targeted region. The rate of hyperploidy for the centromere of chromosome 7 was 26% of the analyzed cells. The signal to nucleus ratio (SNR) for the **EGFR** gene was 2.5.

Interpretation guidelines for **EGFR** Gene Copy Number by FISH:

Ratio of **EGFR** to the centromere of chromosome 7:

- Less than 2.0: No **EGFR** amplification
- Greater than 2.0: **EGFR** amplification

Hyperploidy: Greater than two centromere copies/cell.

SNR: The average number of **EGFR** signals per analyzed cell within the targeted region.

Clinical studies show high **EGFR** gene copy number by FISH analysis to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with **EGFR** tyrosine kinase inhibitors.

[page 2 of 2]
CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION: Right Lower Lobe
PROCEDURE: Lobectomy
TUMOR SIZE: Maximum dimension: 6.0 cm
Minor dimension: 5.0 cm
GROSS SATELLITES: Number of gross satellite lesions: 0
TUMOR TYPE: Invasive adenocarcinoma
HISTOLOGIC GRADE: G2, Moderately differentiated
MICROSCOPIC SATELLITES: Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL
EXTENSION/INVASION OF TUMOR: Visceral pleura
ANGIOLYMPHATIC INVASION: Yes
TUMOR NECROSIS: < or = to 50%
SURGICAL MARGIN INVOLVEMENT: No
SURGICAL MARGIN SITE: Distance of invasive tumor to closest margin: 10 mm, Bronchial margin
INFLAMMATORY(DESMOPLASTIC) REACTION: Mild
N1 LYMPH NODES: Number of N1 lymph nodes positive: 8
Number of N1 lymph nodes examined: 12
EXTRACAPSULAR SPREAD OF N1 METASTASES: Yes
N2 LYMPH NODE GROUPS INVOLVED: Level 4R, Level 12R, Level 7
N2 LYMPH NODES: Number of N2 lymph nodes positive: 6
Number of N2 lymph nodes examined: 7
EXTRACAPSULAR SPREAD OF N2 METASTASES: Yes
UNDERLYING DISEASE(S): Emphysema
T STAGE, PATHOLOGIC: pT2
N STAGE, PATHOLOGIC: pN2
M STAGE, PATHOLOGIC: pMX
ANCILLARY STUDIES: Histochemical stains, FISH studies

Source: NCI Genomic Data Commons file e8b0df2c-bdfe-4153-8d08-d4628d3524d2 (TCGA-50-5936.8D30D2AA-BEF2-4329-944B-99AD5C9D8FC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).